Somatic mutation profile of cancer-model specimen HCM-CSHL-0065-C20-85A (3D Organoid; aliquot HCM-CSHL-0065-C20-85A-01D-A768-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0065-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.3 years (23,111 days).
Specimen HCM-CSHL-0065-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24186ca6-dd8b-4632-850d-f4e7e9f73399.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0065-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0065-C20-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/944ff9e5-be73-475d-9990-209c4a81e79b

The open-access MAF lists 140 somatic variants for this specimen: 80 protein-altering or splice-affecting, 43 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 43, Intron 6, Nonsense Mutation 4, Frame Shift Del 3, 5'Flank 3, 5'UTR 3, 3'UTR 3, Splice Site 2, Splice Region 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 208/208 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPP | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 279/549 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs763916531; called by muse, mutect2, varscan2
- ANGPTL2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs555198827; called by muse, mutect2, varscan2
- APC | c.4128T>A p.Y1376* | Nonsense Mutation (SNP) | VAF 71/71 reads (100%) | catalogued as CD058149, CM106639, COSV57326134, COSV57340615, COSV57378080; called by muse, mutect2, varscan2
- CADPS2 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs368742944, COSV57361048; called by muse, mutect2, varscan2
- CDH11 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 152/246 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1177559829, COSV51768028; called by muse, mutect2, varscan2
- CHGB | c.1700A>G p.N567S | Missense Mutation (SNP) | VAF 68/391 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs751617009; called by muse, mutect2, varscan2
- CHPF2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 88/444 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs764713631; called by muse, mutect2, varscan2
- CLASP1 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 97/205 reads (47%) | catalogued as COSV55330955; called by muse, mutect2, varscan2
- ERICH3 | c.1776T>G p.S592R | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs989948152; called by muse, mutect2
- FBN3 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs571909633, COSV54457414; called by muse, mutect2, varscan2
- FGD1 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 229/230 reads (100%) | catalogued as rs931466859, COSV100910777; called by muse, mutect2, varscan2
- FGF10 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 11/358 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52939846, COSV99240155; called by muse, mutect2
- GPRC5C | c.1021G>A p.V341I (on ENST00000652232; = p.V296I on NM_018653.4) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs201878519; called by muse, mutect2, varscan2
- GRIN2A | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 146/435 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763219483, COSV58061178; called by muse, mutect2, varscan2
- IL20RA | c.222C>T p.F74= | Splice Region (SNP) | VAF 29/141 reads (21%) | catalogued as COSV57361110; called by muse, mutect2, varscan2
- KCNH7 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.887); catalogued as COSV59807697; called by muse, mutect2, varscan2
- KCNN1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs1202217199, COSV55841356; called by muse, mutect2, varscan2
- KIR2DL3 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 194/857 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs779850872; called by muse, varscan2
- KLC1 | c.885G>A p.A295= | Splice Region (SNP) | VAF 84/129 reads (65%) | catalogued as rs943212490, COSV99871737; called by muse, mutect2, varscan2
- LPAR4 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 172/173 reads (99%) | SIFT tolerated (0.95); PolyPhen benign (0.013); catalogued as COSV70912459; called by muse, mutect2, varscan2
- LRP1B | c.9319G>A p.E3107K | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV101262056; called by muse, mutect2, varscan2
- MUC16 | c.16789G>C p.V5597L | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs751532991, COSV67465644, COSV67474328; called by muse, mutect2, varscan2
- NTRK3 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs760692815, COSV62295252, COSV62297183; called by muse, mutect2, varscan2
- NUDCD1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99517070; called by muse, mutect2, varscan2
- NWD2 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 143/208 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58749949; called by muse, mutect2, varscan2
- OR2A14 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 131/695 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68718505; called by muse, mutect2, varscan2
- PCDH17 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 123/725 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1180162744, COSV64975946; called by muse, mutect2, varscan2
- PCDHA3 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 157/445 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV100793854; called by muse, mutect2, varscan2
- PEX6 | c.1131-2A>G p.X377_splice | Splice Site (SNP) | VAF 54/302 reads (18%) | catalogued as rs1299653263; called by muse, varscan2
- PSMD3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 141/332 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752964262, COSV52856469; called by muse, mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 106/372 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- PTPN13 | c.4250G>A p.R1417H (on ENST00000411767 / NM_080683.3; = p.R1398H on NM_006264.3) | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528674242, COSV57408559; called by muse, mutect2, varscan2
- RTL3 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs892209848; called by muse, mutect2, varscan2
- RYR2 | c.11410G>A p.D3804N | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs1260070394; called by muse, mutect2, varscan2
- SYNE1 | c.23137C>T p.R7713C (on ENST00000367255 / NM_182961.4; = p.R7642C on NM_033071.3) | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs761198027, COSV54945602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPOAP1 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); catalogued as rs372248342; called by muse, mutect2, varscan2
- TTN | c.64930G>A p.E21644K (on ENST00000591111; = p.E14220K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | PolyPhen benign (0.103); catalogued as rs376870149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.1960C>A p.L654I | Missense Mutation (SNP) | VAF 16/515 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as COSV56333988; called by muse, mutect2
- USP29 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54146716; called by muse, mutect2, varscan2
- WDFY4 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 85/130 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1471160454; called by muse, mutect2, varscan2
- ZNF496 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 158/202 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs575724088, COSV104399369; called by muse, mutect2, varscan2
- ADAMTS17 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 211/460 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ARHGEF7 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ARMC4 | c.2934C>A p.N978K | Missense Mutation (SNP) | VAF 229/355 reads (65%) | SIFT tolerated (0.64); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CACNA1G | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 89/704 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC185 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 233/326 reads (71%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC93 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHMP2B | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHST14 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 276/610 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMPK2 | c.614C>A p.P205Q | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- COLQ | c.676C>A p.H226N | Missense Mutation (SNP) | VAF 12/444 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CRYBA2 | c.67del p.Q23Rfs*8 | Frame Shift Del (DEL) | VAF 145/348 reads (42%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5529T>A p.S1843R (on ENST00000297405 / NM_001363185.1; = p.S1739R on NM_052900.3) | Missense Mutation (SNP) | VAF 65/550 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYBRD1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 182/470 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DACH2 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- E2F1 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 158/1327 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FRMD4B | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GABRB3 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- GNAT1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 390/624 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN3B | c.1757A>G p.H586R | Missense Mutation (SNP) | VAF 337/685 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEMGN | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 14/476 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- HGF | c.424A>C p.I142L | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HMCN1 | c.10264G>T p.D3422Y | Missense Mutation (SNP) | VAF 144/700 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA4L | c.107+2_107+3dup p.X36_splice | Splice Site (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- IGHA2 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 237/591 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- KIR2DL1 | c.1009A>G p.N337D | Missense Mutation (SNP) | VAF 355/543 reads (65%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NUP85 | c.1799T>A p.L600* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- OR5AP2 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ORC5 | c.572T>A p.L191Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RELN | c.7729T>G p.F2577V | Missense Mutation (SNP) | VAF 151/309 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RLIM | c.875G>T p.R292I | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ROCK2 | c.2822_2823del p.K941Rfs*15 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- SORT1 | c.100_139del p.Q34Cfs*10 | Frame Shift Del (DEL) | VAF 38/70 reads (54%) | called by mutect2, pindel
- SPEF2 | c.1184C>G p.A395G | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); called by muse, mutect2
- SUSD4 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 99/445 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGM2 | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 316/1214 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- UHMK1 | c.383_390delinsTG p.Q128_C130delinsL | In Frame Del (DEL) | VAF 72/543 reads (13%) | called by pindel, varscan2*
- XIRP1 | c.2149G>T p.A717S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZC3H13 | c.1385G>C p.R462T | Missense Mutation (SNP) | VAF 23/892 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- AL031777.2 | c.336C>T p.I112= | Silent (SNP) | VAF 130/201 reads (65%) | catalogued as COSV61911980; called by muse, mutect2, varscan2
- ANO2 | c.1719C>A p.V573= (on ENST00000356134 / NM_001278597.3; = p.V577= on NM_001278596.3) | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV59010751; called by muse, mutect2
- AOPEP | c.1260C>T p.I420= | Silent (SNP) | VAF 272/572 reads (48%) | called by muse, mutect2, varscan2
- ATF7 | c.1443G>A p.S481= (on ENST00000548446 / NM_001366555.2; = p.S470= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 107/340 reads (31%) | catalogued as rs372771818; called by muse, mutect2, varscan2
- AVPR2 | c.396C>A p.A132= | Silent (SNP) | VAF 503/505 reads (100%) | called by muse, mutect2, varscan2
- BRCA2 | c.6192G>A p.K2064= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as rs786202616; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH23 | c.6198G>T p.R2066= | Silent (SNP) | VAF 44/448 reads (10%) | called by muse, mutect2
- CKAP5 | c.888A>G p.R296= | Silent (SNP) | VAF 118/164 reads (72%) | catalogued as rs1431324319; called by muse, mutect2, varscan2
- COQ9 | c.360G>A p.A120= | Silent (SNP) | VAF 193/588 reads (33%) | catalogued as rs200057404, COSV52645458, COSV99346062; called by muse, mutect2, varscan2
- DPEP1 | c.951C>T p.D317= | Silent (SNP) | VAF 184/279 reads (66%) | catalogued as rs766145851; called by muse, mutect2, varscan2
- EDARADD | c.327C>T p.A109= (on ENST00000334232 / NM_145861.4; = p.A99= on NM_080738.4) | Silent (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- ELL | c.861G>A p.V287= | Silent (SNP) | VAF 163/295 reads (55%) | called by muse, mutect2, varscan2
- FAM170B | c.375G>A p.T125= | Silent (SNP) | VAF 162/232 reads (70%) | catalogued as rs992216383; called by muse, mutect2, varscan2
- FAM217B | c.960C>T p.S320= | Silent (SNP) | VAF 50/349 reads (14%) | catalogued as rs1466727629, COSV62564202; called by muse, mutect2, varscan2
- FKBP6 | c.12C>T p.S4= | Silent (SNP) | VAF 87/276 reads (32%) | catalogued as rs1426906046; called by muse, mutect2, varscan2
- FO393400.1 | c.510C>T p.T170= | Silent (SNP) | VAF 130/464 reads (28%) | catalogued as rs551441626, COSV54071131; called by muse, mutect2, varscan2
- HABP4 | c.1218G>A p.P406= | Silent (SNP) | VAF 169/359 reads (47%) | catalogued as rs768573343, COSV64514660, COSV64515009; called by muse, mutect2, varscan2
- HASPIN | c.1677G>T p.L559= | Silent (SNP) | VAF 46/47 reads (98%) | catalogued as COSV53993555; called by muse, mutect2, varscan2
- HPSE2 | c.105C>T p.L35= | Silent (SNP) | VAF 107/351 reads (30%) | called by muse, mutect2, varscan2
- LGALS16 | c.282C>T p.Y94= | Silent (SNP) | VAF 92/408 reads (23%) | catalogued as rs552315094; called by muse, mutect2, varscan2
- LRRN3 | c.732C>T p.Y244= | Silent (SNP) | VAF 99/192 reads (52%) | catalogued as rs760392143, COSV57819205; called by muse, mutect2, varscan2
- MICU3 | c.285G>A p.A95= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- MPDZ | c.1713G>A p.A571= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs940890746, COSV59956216; called by muse, mutect2, varscan2
- NPAP1 | c.1299T>C p.A433= | Silent (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- NTSR1 | c.444C>T p.R148= | Silent (SNP) | VAF 158/867 reads (18%) | catalogued as rs1185324665, COSV65139175; called by muse, varscan2
- NTSR1 | c.447C>T p.D149= | Silent (SNP) | VAF 327/859 reads (38%) | catalogued as rs1167999314, COSV100980669; called by muse, varscan2
- NUP188 | c.3531G>C p.V1177= | Silent (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- OR2T34 | c.213C>T p.L71= | Silent (SNP) | VAF 268/537 reads (50%) | catalogued as rs765524903, COSV100170155; called by muse, varscan2
- PCDHB13 | c.1977C>T p.H659= | Silent (SNP) | VAF 331/640 reads (52%) | catalogued as rs369930086, COSV53402352; called by muse, mutect2, varscan2
- PCDHGA8 | c.300G>A p.P100= | Silent (SNP) | VAF 91/273 reads (33%) | catalogued as COSV53900169; called by muse, mutect2, varscan2
- PRPF6 | c.1584C>T p.A528= | Silent (SNP) | VAF 199/1838 reads (11%) | catalogued as rs112093940; called by muse, mutect2, varscan2
- RLBP1 | c.216G>A p.A72= | Silent (SNP) | VAF 146/284 reads (51%) | catalogued as COSV99175412; called by muse, mutect2, varscan2
- SEL1L2 | c.708A>G p.E236= | Silent (SNP) | VAF 37/317 reads (12%) | called by muse, mutect2, varscan2
- SERPINE2 | c.102G>A p.T34= | Silent (SNP) | VAF 141/293 reads (48%) | catalogued as rs756815633, COSV51460165; called by muse, mutect2, varscan2
- SLC25A2 | c.519C>T p.L173= | Silent (SNP) | VAF 59/216 reads (27%) | called by muse, varscan2
- SLITRK5 | c.906C>A p.T302= | Silent (SNP) | VAF 142/297 reads (48%) | called by muse, mutect2, varscan2
- SPRED3 | c.687C>T p.P229= | Silent (SNP) | VAF 146/291 reads (50%) | called by muse, mutect2, varscan2
- SSC5D | c.2862C>T p.T954= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs556555499, COSV104432524; called by muse, mutect2, varscan2
- TCAP | c.447C>T p.P149= | Silent (SNP) | VAF 144/285 reads (51%) | catalogued as rs45614332; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TMEM132B | c.2757C>T p.C919= | Silent (SNP) | VAF 247/350 reads (71%) | catalogued as rs200940370; called by muse, mutect2, varscan2
- TPO | c.1104G>A p.P368= | Silent (SNP) | VAF 197/439 reads (45%) | catalogued as rs775265404, COSV61100258; called by muse, mutect2, varscan2
- ZFP2 | c.270T>A p.I90= | Silent (SNP) | VAF 80/259 reads (31%) | called by muse, mutect2, varscan2
- ZNF211 | c.1272C>A p.P424= (on ENST00000347302 / NM_198855.4; = p.P437= on NM_006385.5) | Silent (SNP) | VAF 76/335 reads (23%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-903G>A | Intron (SNP) | VAF 89/167 reads (53%) | catalogued as COSV100777677; called by muse, mutect2, varscan2
- ACSF3 | c.*146G>A | 3'UTR (SNP) | VAF 217/717 reads (30%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840622 C>T | 5'Flank (SNP) | VAF 48/373 reads (13%) | catalogued as rs953102685, COSV100006175; called by muse, mutect2, varscan2
- ATG16L2 | c.825-467C>T | Intron (SNP) | VAF 34/46 reads (74%) | catalogued as rs1260170162; called by muse, mutect2, varscan2
- DUSP13 | c.*686C>T | 3'UTR (SNP) | VAF 79/256 reads (31%) | called by muse, mutect2, varscan2
- HEPACAM | c.*9G>T | 3'UTR (SNP) | VAF 9/290 reads (3%) | catalogued as COSV100005909; called by muse, mutect2
- HYPK | c.-92G>C | 5'UTR (SNP) | VAF 106/243 reads (44%) | called by muse, mutect2, varscan2
- HYPK | c.-91G>T | 5'UTR (SNP) | VAF 108/245 reads (44%) | called by muse, mutect2, varscan2
- LY6G5C | c.346-899G>A | Intron (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- NBR2 | n.340T>C | RNA (SNP) | VAF 529/999 reads (53%) | catalogued as rs561096358; called by muse, mutect2, varscan2
- OR11H6 | chr14:20229641 C>T | 3'Flank (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- PDE7B | c.711+118C>T | Intron (SNP) | VAF 68/217 reads (31%) | catalogued as rs750908439, COSV100367475; called by muse, mutect2, varscan2
- RARRES1 | chr3:158734016 C>T | 5'Flank (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- SPINK7 | c.-27A>C | 5'UTR (SNP) | VAF 11/201 reads (5%) | called by muse, mutect2
- STRA6 | c.267-42G>T | Intron (SNP) | VAF 167/317 reads (53%) | called by muse, mutect2, varscan2
- TMEM63B | c.711+23C>T | Intron (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- ZNF578 | chr19:52451350 C>T | 5'Flank (SNP) | VAF 91/324 reads (28%) | called by muse, mutect2, varscan2
